Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9E8, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9E8-01A (Primary Tumor).

[page 1 of 2]
Date of surgery :

Left eye enucleation

Macroscopy

The eyeball measures 26 by 25 by 24 mm with a posterior segment of optic nerve of 5 mm .At the section, presence of a black tumor of the posterior pole. This tumor measures 13 main line. Samples have been made for cryo preservation .The specimen has been then included entirely.

Microscopy

The tumor described macroscopically corresponds to a choroidal melanoma. This proliferation is made of epithelioid (80%) and fusiform cells (20%), with strongly atypical and nucleolated nuclei and abundant cytoplasm often loaded with melanin pigment. The mitotic index is low with 1 mitosis out of 10 high 400 magnification fields. This tumor measures histologically 13 mm of main line. It infiltrates the choroid and the sclera up to the two thirds of its thickness. (slide D). Further more there is a neoplastic endo-lymphatic embol at the external part of the sclera, in the fibrous and fat orbital tissue (slide D). The optic nerve on his entire course and the cut end of the optic nerve are free of tumor. Ciliary processes and meningeal sheaths are free

Conclusion

Mixed type (epithelioid and fusiform) choroidal melanoma

Size of the tumor: 13 mm

Infiltration of the internal two thirds of the sclera

Tumoral embol in the extrascleral orbital fat

The optic nerve on his entire course and the cut end of the optic nerve are free of tumor.
Ciliary processes and meningeal sheaths are free

CLF ICD O 3
Melanoma, epithelioid cell 8771/3
path
Melanoma, epithelioid &
spindle cell mixed 8770/3
Site @ Choroid C69.3

NO 2/10/14

See path discrepancy form for epithelioid and
spindle cell ratio.

HPV Discrepancy		

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	80% epithelioid cells 20% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% epithelioid cells 1-30% spindle cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 403cbfa5-c51d-4ec7-884f-bf008b3a3cc4 (TCGA-V4-A9E8.E143312E-761C-4465-8357-CC44E3987CFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).